Somatic mutation profile of tumor specimen 0E1O0H from CCDI case PBCWPX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E1O0H: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c7d4979-7838-4424-ba6e-dce29f3c4880.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1NYT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a93e2b4-ce57-4aa2-964a-2cf5a56cf26c

The open-access MAF lists 81 somatic variants for this specimen: 55 protein-altering or splice-affecting, 14 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 14, Intron 6, Frame Shift Del 3, 5'UTR 3, 3'UTR 3, In Frame Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 173/303 reads (57%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- TP53 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 118/137 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.1043G>A p.R348Q (on ENST00000614293; = p.R318Q on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 97/194 reads (50%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs113211392; called by muse, mutect2, varscan2
- C5 | c.530T>C p.I177T | Missense Mutation (SNP) | VAF 107/246 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.011); catalogued as COSV56329082; called by muse, mutect2, varscan2
- CFAP46 | c.4120_4122del p.E1374del | In Frame Del (DEL) | VAF 95/196 reads (48%) | catalogued as rs1478282746; called by mutect2, pindel, varscan2
- CPT1B | c.949C>T p.R317W | Missense Mutation (SNP) | VAF 62/133 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753087333; called by muse, mutect2, varscan2
- CTSE | c.562G>A p.G188R (on ENST00000360218; = p.G183R on NM_001910.4) | Missense Mutation (SNP) | VAF 82/330 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1346183642, COSV63059927; called by muse, mutect2, varscan2
- ECPAS | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 68/220 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1382770661; called by muse, mutect2, varscan2
- EPHA5 | c.2966A>G p.N989S | Missense Mutation (SNP) | VAF 97/226 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV56663489; called by muse, mutect2, varscan2
- GALNT13 | c.1313C>A p.T438N | Missense Mutation (SNP) | VAF 102/358 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.073); catalogued as COSV67228746; called by mutect2, varscan2
- GPR15 | c.766C>G p.P256A | Missense Mutation (SNP) | VAF 112/288 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52520888; called by muse, mutect2, varscan2
- IL6 | c.166_169del p.Q56Ffs*11 | Frame Shift Del (DEL) | VAF 113/312 reads (36%) | catalogued as rs1208789133; called by pindel, varscan2
- IQCN | c.521A>C p.Q174P | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV66575429; called by muse, mutect2, varscan2
- MUC16 | c.6959C>T p.T2320I | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as rs764731284; called by muse, mutect2, varscan2
- PANX2 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 117/266 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs1313188842; called by muse, mutect2, varscan2
- PRR32 | c.601C>G p.R201G | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV64420505; called by muse, mutect2
- RTL8B | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs1227743957, COSV66954599; called by muse, mutect2
- SEMA3D | c.1900C>G p.R634G | Missense Mutation (SNP) | VAF 74/252 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV52393734; called by mutect2, varscan2
- SKOR2 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1321867184; called by muse, mutect2, varscan2
- STC1 | c.131G>C p.R44P | Missense Mutation (SNP) | VAF 152/586 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51689389; called by muse, mutect2, varscan2
- TMEM130 | c.1204G>T p.G402W (on ENST00000416379 / NM_001134450.2; = p.G390W on NM_152913.3) | Missense Mutation (SNP) | VAF 91/197 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.73); catalogued as COSV59559220; called by muse, mutect2, varscan2
- ADAMTS18 | c.2213G>C p.C738S | Missense Mutation (SNP) | VAF 171/371 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ADGRB1 | c.3527A>C p.E1176A | Missense Mutation (SNP) | VAF 154/623 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AICDA | c.596G>T p.*199Lext*1 | Nonstop Mutation (SNP) | VAF 96/229 reads (42%) | called by muse, mutect2, varscan2
- AP1S1 | c.304G>C p.D102H | Missense Mutation (SNP) | VAF 138/350 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDAN1 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 85/164 reads (52%) | SIFT tolerated (0.47); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- CDH26 | c.604G>A p.V202I | Missense Mutation (SNP) | VAF 99/531 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- EP300 | c.6265del p.A2089Lfs*45 | Frame Shift Del (DEL) | VAF 124/323 reads (38%) | called by mutect2, pindel, varscan2
- IFT140 | c.567C>G p.S189R | Missense Mutation (SNP) | VAF 173/218 reads (79%) | SIFT tolerated (0.42); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- IGFBP5 | c.454G>C p.V152L | Missense Mutation (SNP) | VAF 38/386 reads (10%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2
- IL16 | c.3742C>G p.L1248V (on ENST00000302987 / NM_172217.5; = p.L547V on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/220 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITK | c.1367C>A p.A456E | Missense Mutation (SNP) | VAF 165/309 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ITPR3 | c.3001G>T p.V1001L | Missense Mutation (SNP) | VAF 162/385 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.142); called by muse, mutect2
- JCHAIN | c.387C>A p.N129K | Missense Mutation (SNP) | VAF 79/237 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- KAT14 | c.164G>A p.S55N | Missense Mutation (SNP) | VAF 85/401 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- LRRCC1 | c.2093A>G p.E698G | Missense Mutation (SNP) | VAF 99/714 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGEB10 | c.876G>T p.L292F | Missense Mutation (SNP) | VAF 99/394 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- MAP3K10 | c.2003G>A p.R668Q | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- MCC | c.412G>C p.V138L | Missense Mutation (SNP) | VAF 111/273 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MORC4 | c.1777C>G p.P593A | Missense Mutation (SNP) | VAF 70/261 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- OR2T3 | c.577T>C p.S193P | Missense Mutation (SNP) | VAF 119/378 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR51I1 | c.496A>G p.K166E | Missense Mutation (SNP) | VAF 91/340 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PAF1 | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 100/307 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PKHD1L1 | c.8524G>A p.V2842I | Missense Mutation (SNP) | VAF 226/567 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- POMT2 | c.1963T>C p.F655L | Missense Mutation (SNP) | VAF 96/273 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- RAPGEF2 | c.2968G>A p.E990K | Missense Mutation (SNP) | VAF 65/274 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RASA2 | c.731A>G p.E244G | Missense Mutation (SNP) | VAF 93/215 reads (43%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ROM1 | c.674G>T p.C225F | Missense Mutation (SNP) | VAF 116/355 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SENP7 | c.2042C>T p.S681L | Missense Mutation (SNP) | VAF 140/305 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TCEAL5 | c.92A>G p.E31G | Missense Mutation (SNP) | VAF 29/460 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.639); called by muse, mutect2
- TIPRL | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 176/312 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UNC80 | c.4907del p.P1636Rfs*7 | Frame Shift Del (DEL) | VAF 37/304 reads (12%) | called by mutect2, pindel, varscan2
- VWA5B1 | c.2364C>A p.D788E | Missense Mutation (SNP) | VAF 106/189 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR6 | c.2332C>G p.R778G | Missense Mutation (SNP) | VAF 91/257 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ZNF41 | c.82T>G p.S28A | Missense Mutation (SNP) | VAF 57/246 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); called by muse, mutect2, varscan2
- ACTRT1 | c.942C>A p.L314= | Silent (SNP) | VAF 98/219 reads (45%) | called by muse, mutect2, varscan2
- ARAP3 | c.2517C>A p.G839= | Silent (SNP) | VAF 175/337 reads (52%) | called by muse, mutect2, varscan2
- ARID1B | c.5208G>A p.E1736= | Silent (SNP) | VAF 153/343 reads (45%) | called by muse, mutect2, varscan2
- CPT1B | c.948T>G p.T316= | Silent (SNP) | VAF 62/133 reads (47%) | called by muse, mutect2, varscan2
- CTAGE6 | c.840T>C p.A280= | Silent (SNP) | VAF 20/158 reads (13%) | called by muse, mutect2
- FAM169A | c.1605T>C p.N535= | Silent (SNP) | VAF 134/275 reads (49%) | called by muse, mutect2, varscan2
- FHL1 | c.810G>T p.P270= | Silent (SNP) | VAF 136/311 reads (44%) | called by muse, mutect2, varscan2
- GIMAP1 | c.456C>T p.T152= | Silent (SNP) | VAF 74/189 reads (39%) | catalogued as rs779789140; called by muse, mutect2, varscan2
- IVNS1ABP | c.681T>G p.A227= | Silent (SNP) | VAF 122/345 reads (35%) | called by muse, mutect2, varscan2
- MED13L | c.2403A>G p.T801= | Silent (SNP) | VAF 77/197 reads (39%) | called by muse, mutect2, varscan2
- NR0B1 | c.279A>G p.A93= | Silent (SNP) | VAF 13/226 reads (6%) | called by muse, mutect2
- SEPTIN3 | c.264C>A p.R88= | Silent (SNP) | VAF 143/352 reads (41%) | called by muse, mutect2, varscan2
- TBX21 | c.1332G>A p.P444= | Silent (SNP) | VAF 115/396 reads (29%) | catalogued as rs200867606, COSV51597161; called by muse, mutect2, varscan2
- TNK2 | c.1995G>A p.Q665= | Silent (SNP) | VAF 102/205 reads (50%) | called by muse, mutect2, varscan2
- CCL4 | c.*12A>G | 3'UTR (SNP) | VAF 105/251 reads (42%) | called by muse, mutect2, varscan2
- CLDN5 | c.-12T>A | 5'UTR (SNP) | VAF 75/194 reads (39%) | called by muse, mutect2, varscan2
- DST | c.4297-4368A>G | Intron (SNP) | VAF 123/281 reads (44%) | catalogued as rs1343135166; called by muse, mutect2, varscan2
- GRIA2 | c.89-53T>C | Intron (SNP) | VAF 54/118 reads (46%) | called by muse, mutect2, varscan2
- JAG1 | c.2344+90C>T | Intron (SNP) | VAF 16/58 reads (28%) | called by mutect2, varscan2
- LAS1L | c.362+17G>A | Intron (SNP) | VAF 26/356 reads (7%) | called by muse, mutect2
- MLPH | c.111-31A>G | Intron (SNP) | VAF 16/156 reads (10%) | catalogued as rs1277443268; called by muse, mutect2
- NEBL | c.*39C>A | 3'UTR (SNP) | VAF 67/123 reads (54%) | catalogued as COSV101009182; called by muse, mutect2, varscan2
- OPRK1 | c.*97A>G | 3'UTR (SNP) | VAF 24/290 reads (8%) | called by muse, mutect2
- SGCZ | c.-6C>T | 5'UTR (SNP) | VAF 59/429 reads (14%) | catalogued as COSV101171339; called by muse, mutect2, varscan2
- SLC12A4 | c.1397-97T>G | Intron (SNP) | VAF 30/65 reads (46%) | called by muse, mutect2, varscan2
- TAF1L | c.-24C>T | 5'UTR (SNP) | VAF 37/114 reads (32%) | catalogued as rs773992512, COSV54268909; called by muse, mutect2, varscan2
